Gene-level copy-number profile of tumor specimen TCGA-CN-A498-01A from TCGA case TCGA-CN-A498, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 61.1 years (22,330 days).
Specimen TCGA-CN-A498-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.5ce22438-9aa2-4523-bdff-abf305b08cf0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-A498-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/30f95e30-632e-444c-b0e2-e4e495c343b1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 2: 6,737; copy number 3: 570; copy number 4: 44,644; copy number 5: 1,528; copy number 6: 4,520; copy number 7: 6; copy number 8: 1,753; copy number 13: 1; copy number 32: 24; copy number 35: 15; copy number 49: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-A498-01A-11D-A24C-01): tumor purity 0.54, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:54,048,007–54,075,583, 2 genes: RN7SL801P, AC016601.1.
- chr9:21,929,457–21,995,301, 3 genes (within-gene range 0–4): ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:33,817,160–33,920,399, 1 gene (within-gene range 0–4): UBE2R2.
- chr9:33,868,540–33,868,665, 1 gene: RNU4ATAC11P.
- chr17:4,163,821–4,263,995, 1 gene (within-gene range 0–4): ANKFY1.
- chr17:4,222,091–4,366,628, 4 genes (within-gene range 0–4): RYKP1, AC087742.1, UBE2G1, MFSD1P1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 47 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:69,147,228–69,171,564, 1 gene, copy number 13 (within-gene range 6–13): AP003071.2.
- chr11:69,294,151–71,252,577, 46 genes, copy number 32–49 (within-gene range 2–49): MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
